HCMI case HCM-BROD-0339-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b84c894-91d7-4c3e-8f17-4d6adc8bb468

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 36.3 years (13,251 days); AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 11,576 days (31.7 years); Days to treatment end: 11,601 days (31.8 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 11,627 days (31.8 years); Days to treatment end: 11,977 days (32.8 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 67.8 years (24,765 days); Days to diagnosis: 11,514 days (31.5 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 18.

Follow-up (2 entries)
- Days to follow up: 12,327 days (33.7 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 11,977.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 173 cm; BMI: 35.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0339-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0339-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0339-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
